Somatic mutation profile of tumor specimen TCGA-A2-A04X-01A (aliquot TCGA-A2-A04X-01A-21W-A050-09) from TCGA case TCGA-A2-A04X, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 34.6 years (12,642 days).
Specimen TCGA-A2-A04X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cded7aec-1491-4235-8544-6d11817a6362.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A04X-10A (Blood Derived Normal), aliquot TCGA-A2-A04X-10A-01W-A055-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/02503808-2c6f-4c41-9928-660c1d1b11b1

The open-access MAF lists 35 somatic variants for this specimen: 23 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 10, Nonsense Mutation 2, Frame Shift Del 1, Splice Site 1, 3'UTR 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CA9 | c.334G>T p.D112Y | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV65675795; called by muse, mutect2, varscan2
- CACNA1B | c.5375C>T p.T1792M | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1284463864, COSV53128141; called by muse, mutect2
- COL1A2 | c.1562C>T p.A521V | Missense Mutation (SNP) | VAF 33/173 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.433); catalogued as rs140434765; called by muse, mutect2, varscan2
- CYSLTR2 | c.62G>A p.G21D | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV56165994, COSV99935295; called by muse, mutect2, varscan2
- DNAH17 | c.1951G>T p.D651Y | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as COSV67755514; called by muse, mutect2, varscan2
- DNAH3 | c.10372G>A p.E3458K | Missense Mutation (SNP) | VAF 47/247 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.438); catalogued as COSV54525043; called by muse, mutect2, varscan2
- EEA1 | c.1153G>C p.E385Q | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); catalogued as COSV59286121; called by muse, mutect2, varscan2
- FBXO11 | c.1771G>A p.D591N (on ENST00000403359 / NM_001190274.2; = p.D507N on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.249); catalogued as COSV57020163; called by muse, mutect2, varscan2
- GTPBP3 | c.18G>C p.W6C | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.258); catalogued as COSV50179099; called by muse, mutect2, varscan2
- HOMER3 | c.880C>T p.Q294* | Nonsense Mutation (SNP) | VAF 6/76 reads (8%) | catalogued as COSV55356304; called by muse, mutect2
- IPO4 | c.311C>T p.S104L | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as COSV55779388; called by muse, mutect2, varscan2
- LRP2 | c.7867G>C p.G2623R | Missense Mutation (SNP) | VAF 53/220 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55553044, COSV55555770; called by muse, mutect2, varscan2
- NNT | c.3171C>G p.F1057L | Missense Mutation (SNP) | VAF 44/184 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52925431; called by muse, mutect2, varscan2
- OGN | c.839G>C p.G280A | Missense Mutation (SNP) | VAF 59/227 reads (26%) | SIFT tolerated (0.82); PolyPhen benign (0.026); catalogued as COSV52761048; called by muse, mutect2, varscan2
- PDZRN3 | c.1939C>T p.R647C | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as rs746378403, COSV55193847, COSV55195895, COSV55201867; called by muse, mutect2, varscan2
- SARM1 | c.2065G>T p.E689* | Nonsense Mutation (SNP) | VAF 37/147 reads (25%) | catalogued as COSV50229426, COSV50229624; called by muse, mutect2, varscan2
- STK31 | c.2240G>C p.R747P | Missense Mutation (SNP) | VAF 68/266 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV100669870, COSV63456426; called by muse, mutect2, varscan2
- TLL1 | c.1265G>C p.R422T | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50273215, COSV50287064; called by muse, mutect2
- VPS53 | c.375G>A p.V125= (on ENST00000571805 / NM_001366253.2; = p.V96= on NM_018289.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 89/301 reads (30%) | catalogued as COSV52131436; called by muse, mutect2, varscan2
- WIF1 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.988); catalogued as COSV54132275; called by muse, mutect2, varscan2
- YY1AP1 | c.2261G>A p.G754E (on ENST00000295566 / NM_139118.2; = p.G697E on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/659 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV55121674, COSV55124443; called by muse, mutect2
- ST3GAL6 | c.907_909+35del p.X303_splice | Splice Site (DEL) | VAF 54/316 reads (17%) | called by mutect2, pindel
- UBE2Q1 | c.418_421del p.K140Gfs*9 | Frame Shift Del (DEL) | VAF 25/179 reads (14%) | called by pindel, varscan2
- CARMIL1 | c.3468G>A p.R1156= | Silent (SNP) | VAF 60/276 reads (22%) | catalogued as COSV61518097; called by muse, mutect2, varscan2
- FLAD1 | c.516T>C p.H172= | Silent (SNP) | VAF 30/410 reads (7%) | catalogued as rs1258748448, COSV52697312; called by muse, mutect2
- GSTA5 | c.183C>T p.D61= | Silent (SNP) | VAF 62/304 reads (20%) | catalogued as rs765250714, COSV52862387; called by muse, mutect2, varscan2
- ITGB1 | c.384A>G p.P128= | Silent (SNP) | VAF 25/91 reads (27%) | catalogued as COSV56482201; called by muse, mutect2, varscan2
- PRPH | c.162G>A p.S54= | Silent (SNP) | VAF 2/8 reads (25%) | catalogued as COSV57678661; called by muse, mutect2
- PTK7 | c.918G>A p.Q306= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV57848929; called by muse, mutect2, varscan2
- SHROOM4 | c.2538C>T p.S846= | Silent (SNP) | VAF 50/196 reads (26%) | catalogued as COSV56790081; called by muse, mutect2, varscan2
- WTAP | c.405G>T p.L135= | Silent (SNP) | VAF 61/194 reads (31%) | catalogued as COSV61610166; called by muse, mutect2, varscan2
- ZHX3 | c.1599C>T p.L533= | Silent (SNP) | VAF 40/182 reads (22%) | catalogued as rs1303334905, COSV58383905; called by muse, mutect2, varscan2
- ZNF213 | c.1287C>T p.F429= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as rs761524884, COSV67727814; called by mutect2, varscan2
- HERC2P3 | n.382C>G | RNA (SNP) | VAF 34/621 reads (5%) | called by muse, mutect2
- RBM46 | c.*2G>C | 3'UTR (SNP) | VAF 20/71 reads (28%) | catalogued as COSV99907887; called by muse, mutect2, varscan2
